Somatic mutation profile of tumor specimen TCGA-MN-A4N4-01A (aliquot TCGA-MN-A4N4-01A-12D-A24P-08) from TCGA case TCGA-MN-A4N4, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 57.2 years (20,888 days).
Specimen TCGA-MN-A4N4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f783b9df-75c8-46cf-8859-be1f3b440d53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MN-A4N4-10A (Blood Derived Normal), aliquot TCGA-MN-A4N4-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4af323b6-4726-4635-a118-7232c7785f35

The open-access MAF lists 1,570 somatic variants for this specimen: 1,204 protein-altering or splice-affecting, 327 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,029, Silent 327, Nonsense Mutation 92, Splice Site 32, Frame Shift Del 31, Intron 15, RNA 14, Splice Region 9, Frame Shift Ins 7, 3'UTR 3, 3'Flank 3, Translation Start Site 2.

Variants (750 of 1,570; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 32/144 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as COSV57246601, COSV57252959; called by muse, mutect2, varscan2
- ERCC6 | c.2203C>T p.R735* | Nonsense Mutation (SNP) | VAF 65/227 reads (29%) | catalogued as rs121917901, CM980626; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.2641G>T p.E881* | Nonsense Mutation (SNP) | VAF 55/136 reads (40%) | catalogued as COSV100589120; called by muse, mutect2, varscan2
- A2ML1 | c.2908T>A p.C970S | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100229681; called by muse, mutect2, varscan2
- AADACL4 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100879528; called by muse, mutect2, varscan2
- ABCA1 | c.2066G>C p.S689T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV101037825, COSV66069668; called by muse, mutect2, varscan2
- ABCA9 | c.942+1G>C p.X314_splice | Splice Site (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100383677; called by muse, mutect2, varscan2
- ABCB11 | c.2904G>C p.E968D | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV99793479; called by muse, mutect2
- ABCC10 | c.275G>T p.G92V (on ENST00000372530 / NM_001198934.2; = p.G49V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99768279; called by muse, mutect2, varscan2
- ABCC2 | c.4149C>A p.D1383E | Missense Mutation (SNP) | VAF 75/438 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100966801; called by muse, mutect2, varscan2
- ABCC9 | c.1063G>C p.A355P | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99687819; called by muse, mutect2, varscan2
- ACCSL | c.1573C>A p.P525T | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101122342, COSV66581436; called by muse, mutect2, varscan2
- ACOT12 | c.545C>A p.S182Y | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100297256; called by muse, mutect2, varscan2
- ACP7 | c.904C>A p.H302N | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.157); catalogued as COSV100488671; called by muse, mutect2, varscan2
- ACSM5 | c.624-1G>A p.X208_splice | Splice Site (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100088188, COSV100089757; called by muse, mutect2, varscan2
- ACSS3 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99699667; called by muse, mutect2, varscan2
- ACTN2 | c.1645G>C p.E549Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as COSV100857127; called by muse, mutect2
- ACTR10 | c.519-1G>A p.X173_splice | Splice Site (SNP) | VAF 5/18 reads (28%) | catalogued as COSV99581426; called by muse, mutect2, varscan2
- ACTR10 | c.659T>G p.L220R | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV99581428; called by muse, mutect2, varscan2
- ADAM11 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184207190, COSV52346439; called by muse, mutect2, varscan2
- ADAM7 | c.1959A>T p.E653D | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99445461; called by muse, mutect2
- ADAMTS10 | c.196C>A p.R66S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.164); catalogued as COSV54353199, COSV99547557; called by muse, mutect2, varscan2
- ADAMTS16 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as rs777481925, COSV99941139, COSV99943598; called by muse, mutect2
- ADAMTS20 | c.1913A>T p.N638I | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV101240755; called by muse, mutect2
- ADAMTS20 | c.1487G>C p.G496A | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316681814, COSV101240757; called by muse, mutect2
- ADAMTS20 | c.1326C>A p.S442R | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.398); catalogued as COSV101240761; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2389T>A p.W797R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV101002134; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1757T>G p.V586G | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs1408673892, COSV99721950; called by muse, mutect2, varscan2
- ADAR | c.3278A>T p.D1093V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV99426962; called by muse, mutect2, varscan2
- ADAR | c.3277G>A p.D1093N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99426965; called by muse, mutect2, varscan2
- ADCY8 | c.1669G>C p.D557H | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99655066; called by muse, mutect2, varscan2
- ADGRB3 | c.4211G>T p.G1404V | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.984); catalogued as rs1460422620, COSV53251657; called by muse, mutect2, varscan2
- ADGRE1 | c.2253C>G p.I751M | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99166049; called by muse, mutect2
- ADGRF4 | c.1235C>G p.S412* | Nonsense Mutation (SNP) | VAF 11/142 reads (8%) | catalogued as COSV99348929; called by muse, mutect2
- ADGRG4 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as COSV99796175; called by muse, mutect2, varscan2
- ADGRL3 | c.1936C>A p.Q646K (on ENST00000506720 / NM_001322402.2; = p.Q578K on NM_015236.6) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as COSV100800396; called by muse, mutect2, varscan2
- ADGRL3 | c.3697C>A p.R1233S (on ENST00000506720 / NM_001322402.2; = p.R1165S on NM_015236.6) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV101547065, COSV101547455, COSV72231046; called by muse, mutect2, varscan2
- ADGRV1 | c.12044G>C p.G4015A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV101316713; called by muse, mutect2
- AEBP1 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); catalogued as COSV99789208; called by muse, varscan2
- AFF1 | c.2882A>T p.K961I | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100321181; called by muse, mutect2, varscan2
- AFF2 | c.2327C>A p.P776Q | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.85); PolyPhen benign (0.023); catalogued as COSV99667028; called by muse, mutect2, varscan2
- AGMO | c.27T>A p.D9E | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100694981; called by muse, mutect2, varscan2
- AGO4 | c.2012G>T p.G671V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV100943143; called by muse, mutect2, varscan2
- AHDC1 | c.3335A>T p.Q1112L | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99899867; called by muse, varscan2
- AHNAK | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV57208245, COSV99950261; called by muse, mutect2, varscan2
- AHSG | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs148092737, COSV56608314; called by muse, mutect2, varscan2
- AICDA | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV99984430; called by muse, mutect2, varscan2
- AJAP1 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as COSV100982081; called by muse, mutect2, varscan2
- AKAP1 | c.2383G>T p.D795Y | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100533241; called by muse, mutect2, varscan2
- AKAP5 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 10/170 reads (6%) | catalogued as COSV100278122; called by muse, mutect2
- AKAP6 | c.2347-1G>T p.X783_splice | Splice Site (SNP) | VAF 33/90 reads (37%) | catalogued as COSV99805472; called by muse, mutect2, varscan2
- AKAP9 | c.11329G>C p.E3777Q (on ENST00000359028; = p.E3753Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.856); catalogued as COSV100663401; called by muse, mutect2, varscan2
- AKR1D1 | c.140C>A p.T47K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV99653347; called by muse, mutect2, varscan2
- AKT2 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); catalogued as rs769806554, COSV100251889, COSV60909544; called by mutect2, varscan2
- AKT2 | c.996C>A p.D332E | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100251893; called by muse, mutect2
- AL121899.2 | c.266C>G p.T89R | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101198725, COSV67349952; called by muse, mutect2
- AL592490.1 | c.2542A>T p.S848C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101308319; called by muse, mutect2
- ALPK1 | c.3280G>T p.E1094* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV99455443; called by muse, mutect2
- ALS2 | c.3513-1G>T p.X1171_splice | Splice Site (SNP) | VAF 17/92 reads (18%) | catalogued as COSV99970218; called by muse, mutect2, varscan2
- AMIGO3 | c.1274C>G p.P425R | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100246799, COSV57540089; called by muse, mutect2, varscan2
- AMTN | c.396C>A p.F132L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100219890; called by muse, mutect2, varscan2
- AMY2A | c.49T>C p.Y17H | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV101340691; called by muse, mutect2, varscan2
- ANK2 | c.9941C>A p.P3314Q | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); catalogued as COSV52180716; called by muse, mutect2
- ANK2 | c.11125C>A p.P3709T | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100004861; called by muse, mutect2
- ANKAR | c.2603C>T p.P868L | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV99854849; called by muse, mutect2
- ANKRD17 | c.5905C>T p.P1969S | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.021); catalogued as COSV100430169; called by muse, mutect2, varscan2
- ANKRD44 | c.1952G>T p.R651L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as COSV99986286; called by muse, mutect2, varscan2
- ANO2 | c.1115C>A p.P372Q (on ENST00000356134 / NM_001278597.3; = p.P376Q on NM_001278596.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100502738, COSV59024311; called by muse, mutect2, varscan2
- ANO2 | c.1114C>A p.P372T (on ENST00000356134 / NM_001278597.3; = p.P376T on NM_001278596.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100502744; called by muse, mutect2, varscan2
- AP002512.3 | c.52C>A p.R18S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs369480096, COSV100392734; called by muse, mutect2, varscan2
- AP3B2 | c.3074C>A p.A1025D (on ENST00000261722; = p.A1019D on NM_004644.5) | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99917177; called by muse, mutect2, varscan2
- AP3M2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99442054; called by muse, mutect2, varscan2
- APOL5 | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99968497; called by muse, mutect2, varscan2
- APP | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); catalogued as COSV100696381; called by muse, mutect2, varscan2
- AQP1 | c.338C>G p.S113* | Nonsense Mutation (SNP) | VAF 11/192 reads (6%) | catalogued as COSV61266810, COSV61267959, COSV61268717; called by muse, mutect2
- AR | c.1906G>T p.G636C | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101019842; called by muse, mutect2
- ARFGEF1 | c.2440G>T p.G814* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99145593, COSV99145683; called by muse, mutect2, varscan2
- ARHGAP15 | c.384G>T p.M128I | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99714693; called by muse, mutect2, varscan2
- ARHGAP28 | c.726G>T p.V242= (on ENST00000383472 / NM_001366230.1; = p.V83= on NM_001010000.3) | Splice Region (SNP) | VAF 55/174 reads (32%) | catalogued as COSV99151703; called by muse, mutect2, varscan2
- ARHGAP31 | c.3748G>T p.D1250Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1324517108, COSV99957976; called by muse, mutect2, varscan2
- ARHGAP6 | c.1907C>A p.S636* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV100273710; called by muse, varscan2
- ARHGAP6 | c.1208T>A p.L403Q | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100273711; called by muse, mutect2, varscan2
- ARHGEF12 | c.2056G>C p.G686R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.693); catalogued as COSV100755322; called by muse, mutect2
- ARHGEF3 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1361626014, COSV99576176; called by muse, mutect2, varscan2
- ARHGEF40 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); catalogued as COSV100070834; called by muse, mutect2
- ARID1A | c.3060G>T p.R1020S | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61373857, COSV61380399; called by muse, mutect2, varscan2
- ARID2 | c.3272G>C p.R1091T | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.549); catalogued as COSV100537273; called by muse, mutect2, varscan2
- ARMC5 | c.340G>T p.V114L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as COSV99192303, COSV99192980; called by muse, mutect2, varscan2
- ARSG | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101477939, COSV71593752; called by muse, mutect2, varscan2
- ASAP1 | c.1515+1G>T p.X505_splice | Splice Site (SNP) | VAF 20/99 reads (20%) | catalogued as COSV100728075; called by muse, mutect2, varscan2
- ASB3 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99711699; called by muse, mutect2, varscan2
- ASPM | c.3476A>T p.D1159V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV99661369; called by muse, mutect2, varscan2
- ASPM | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV99661371; called by muse, mutect2
- ASTN1 | c.2937G>C p.Q979H | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as rs756032018, COSV100708140, COSV62497240; called by muse, mutect2
- ASTN1 | c.2211G>C p.K737N | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as COSV56060462, COSV99923621; called by muse, mutect2
- ASTN1 | c.342G>T p.E114D | Missense Mutation (SNP) | VAF 60/216 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs777773361; called by muse, mutect2, varscan2
- ASXL3 | c.1846G>C p.E616Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV52463758; called by muse, mutect2, varscan2
- ATF6B | c.805C>A p.L269M | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as COSV100916865, COSV64351537; called by muse, mutect2
- ATF7IP | c.2836A>T p.K946* | Nonsense Mutation (SNP) | VAF 12/93 reads (13%) | catalogued as COSV99662344; called by muse, mutect2, varscan2
- ATM | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV99592581; called by muse, mutect2
- ATM | c.1947A>T p.E649D | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99592582; called by muse, mutect2, varscan2
- ATP13A4 | c.2953A>T p.M985L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100710861; called by muse, mutect2, varscan2
- ATP1A2 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as COSV100768249, COSV63405240; called by muse, mutect2
- ATP2B1 | c.554A>G p.Q185R | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99666334; called by muse, mutect2, varscan2
- ATP2B2 | c.3250G>A p.A1084T (on ENST00000352432; = p.A1050T on NM_001683.5) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100660648; called by muse, mutect2, varscan2
- ATXN7L2 | c.1373C>A p.A458E | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100149986; called by muse, mutect2, varscan2
- AVPR1B | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV100899486, COSV65637942; called by muse, mutect2, varscan2
- B4GALT1 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101123024; called by muse, mutect2, varscan2
- BBS7 | c.1879G>A p.D627N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV99145203; called by muse, mutect2
- BCL6 | c.1641G>T p.K547N | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99216161; called by muse, mutect2, varscan2
- BEND2 | c.2135T>A p.L712Q | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.437); catalogued as COSV101192301; called by muse, mutect2, varscan2
- BFSP1 | c.1403A>G p.E468G | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100925472; called by muse, mutect2, varscan2
- BLZF1 | c.906G>T p.L302F | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100250893; called by muse, mutect2, varscan2
- BMP3 | c.898A>T p.N300Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99262119; called by muse, mutect2, varscan2
- BOD1L1 | c.8071G>A p.E2691K | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.118); catalogued as COSV99240653; called by muse, mutect2, varscan2
- BRINP3 | c.1695G>T p.L565F | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100818345, COSV100819197; called by muse, varscan2
- BRINP3 | c.1633A>C p.S545R | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV100819579, COSV66524852; called by muse, varscan2
- BTAF1 | c.4850C>T p.S1617L | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV56429799, COSV56433860; called by muse, mutect2
- BTBD7 | c.2041G>T p.G681C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100598316, COSV58289953; called by muse, mutect2, varscan2
- BTN3A1 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV99176487; called by muse, mutect2
- C12orf40 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 92/159 reads (58%) | catalogued as COSV100210946; called by muse, mutect2, varscan2
- C16orf92 | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV99662641; called by muse, mutect2, varscan2
- C1orf141 | c.571G>T p.V191F | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV100924417; called by muse, mutect2
- C1orf50 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV100998169; called by muse, mutect2
- CACNA1C | c.2741G>T p.S914I | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100223684, COSV59780578; called by muse, mutect2, varscan2
- CACNA1C | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0.325); catalogued as COSV100223688; called by muse, mutect2
- CACNA1E | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV100706139; called by muse, varscan2
- CACNA1E | c.1960C>A p.L654M | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100706142, COSV62401261; called by muse, mutect2, varscan2
- CACNA1F | c.5265-1G>T p.X1755_splice | Splice Site (SNP) | VAF 9/18 reads (50%) | catalogued as COSV100545535; called by muse, mutect2, varscan2
- CACNA1H | c.2170G>C p.G724R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as COSV100673533, COSV100673729; called by muse, mutect2, varscan2
- CACNA2D4 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54948000; called by muse, mutect2, varscan2
- CALHM2 | c.51G>C p.K17N | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV99588665, COSV99588861; called by muse, mutect2
- CALN1 | c.248G>C p.R83P (on ENST00000329008 / NM_001017440.3; = p.R125P on NM_031468.4) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100210142, COSV61119556; called by muse, varscan2
- CALN1 | c.206G>T p.G69V (on ENST00000329008 / NM_001017440.3; = p.G111V on NM_031468.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100210144; called by muse, varscan2
- CAMK2B | c.935G>T p.R312L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV99323696; called by muse, mutect2, varscan2
- CAPN11 | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746096764, COSV101291995; called by muse, mutect2, varscan2
- CAPS2 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100158486; called by muse, mutect2, varscan2
- CARMIL1 | c.1010C>G p.S337C | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV100279089; called by muse, mutect2
- CASS4 | c.643-1G>T p.X215_splice | Splice Site (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100825013; called by muse, varscan2
- CAST | c.1252G>C p.A418P (on ENST00000341926; = p.A501P on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV100352780; called by muse, mutect2, varscan2
- CCDC114 | c.672C>G p.H224Q | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV100197205; called by muse, mutect2, varscan2
- CCDC115 | c.289C>A p.R97S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99383897; called by muse, mutect2, varscan2
- CCDC122 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as COSV99866188; called by muse, mutect2, varscan2
- CCDC190 | c.357G>C p.K119N | Missense Mutation (SNP) | VAF 83/350 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); catalogued as rs1410159870, COSV100905850; called by muse, mutect2, varscan2
- CCDC30 | c.666G>T p.M222I (on ENST00000340612; = p.M179I on NM_001080850.3) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.031); catalogued as COSV100501800; called by muse, mutect2, varscan2
- CCDC42 | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as COSV99549691; called by muse, mutect2, varscan2
- CCDC88C | c.5933C>T p.P1978L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780317326, COSV57796178; called by muse, mutect2, varscan2
- CCPG1 | c.103A>T p.S35C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.707); catalogued as COSV100197581; called by muse, mutect2, varscan2
- CCR6 | c.1121T>C p.M374T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV100551231; called by muse, mutect2, varscan2
- CCSER1 | c.1301G>C p.G434A | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100397545; called by muse, mutect2
- CCT2 | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV100167864; called by muse, mutect2, varscan2
- CD200R1 | c.587G>C p.G196A (on ENST00000471858 / NM_170780.3; = p.G219A on NM_138806.4) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99867983, COSV99868064; called by muse, mutect2, varscan2
- CD28 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.116); catalogued as rs1202305808, COSV100142647, COSV99048002; called by muse, mutect2
- CDC25C | c.830C>G p.S277C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.72); catalogued as COSV100087008; called by muse, mutect2
- CDCA8 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as rs376693211; called by muse, mutect2, varscan2
- CDH11 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV51771466; called by muse, mutect2, varscan2
- CDH12 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1430637745, COSV66396911; called by muse, mutect2
- CDH26 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV99723212; called by muse, mutect2, varscan2
- CDH7 | c.1864G>T p.V622L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV100543509; called by muse, mutect2, varscan2
- CDIN1 | c.722G>T p.G241V (on ENST00000437989; = p.G143V on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100590143; called by muse, mutect2, varscan2
- CEBPE | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99247753; called by muse, mutect2
- CEL | c.814G>T p.G272C (on ENST00000673714; = p.G269C on NM_001807.6) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV100672913; called by muse, mutect2, varscan2
- CELF4 | c.1339G>T p.V447L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100612235; called by muse, mutect2
- CELSR3 | c.3001C>T p.Q1001* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as COSV99375488; called by muse, mutect2, varscan2
- CFAP206 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99740249; called by muse, mutect2, varscan2
- CFAP46 | c.6035C>A p.P2012Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as COSV99585841; called by muse, mutect2, varscan2
- CFAP61 | c.1922C>G p.S641C | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99847109; called by muse, mutect2
- CFAP61 | c.2308T>C p.C770R | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99847111; called by muse, varscan2
- CGN | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV99643047; called by muse, mutect2
- CGN | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV54970329, COSV99643058; called by muse, mutect2
- CHD2 | c.1204A>T p.S402C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100560985; called by muse, mutect2, varscan2
- CHD4 | c.1660T>C p.C554R (on ENST00000357008 / NM_001363606.2; = p.C567R on NM_001273.5) | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.157); catalogued as COSV100539587; called by muse, mutect2, varscan2
- CHD6 | c.6211G>T p.A2071S | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.049); catalogued as COSV100951411; called by muse, mutect2, varscan2
- CHGB | c.1375C>A p.H459N | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV66760758; called by muse, mutect2, varscan2
- CHPF | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758106868, COSV99705447; called by muse, mutect2, varscan2
- CIP2A | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV55417640; called by muse, mutect2
- CKAP5 | c.4960C>T p.R1654W (on ENST00000529230 / NM_001008938.4; = p.R1594W on NM_014756.3) | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs752446179, COSV100371640; called by muse, mutect2, varscan2
- CLASRP | c.905+1G>C p.X302_splice | Splice Site (SNP) | VAF 12/121 reads (10%) | catalogued as COSV99674252; called by muse, mutect2, varscan2
- CLCN6 | c.2393G>T p.R798L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.605); catalogued as rs769924243, COSV100412290, COSV56740330; called by muse, mutect2, varscan2
- CLEC16A | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV101278650; called by muse, mutect2, varscan2
- CLGN | c.1454C>A p.A485E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV100346895; called by muse, mutect2, varscan2
- CLIC5 | c.1066-1G>C p.X356_splice (on ENST00000185206 / NM_001370649.1; = p.X197_splice on NM_016929.5) | Splice Site (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99485639; called by muse, mutect2, varscan2
- CLK3 | c.1433A>T p.H478L (on ENST00000395066 / NM_001130028.1; = p.H330L on NM_003992.4) | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100166234; called by muse, mutect2, varscan2
- CMKLR1 | c.940A>T p.I314F (on ENST00000312143 / NM_001142344.2; = p.I312F on NM_004072.3) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV100379685; called by muse, mutect2, varscan2
- CMKLR1 | c.779A>G p.K260R (on ENST00000312143 / NM_001142344.2; = p.K258R on NM_004072.3) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.572); catalogued as COSV100379687; called by muse, mutect2, varscan2
- CNIH4 | c.69C>T p.F23= | Splice Region (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100837027, COSV100837072; called by muse, mutect2, varscan2
- CNPY3 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV65709983; called by muse, mutect2, varscan2
- CNTNAP4 | c.417C>G p.D139E | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); catalogued as COSV100273823; called by muse, mutect2, varscan2
- COL11A1 | c.3031C>A p.P1011T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs578210032, COSV100618405; called by muse, mutect2, varscan2
- COL12A1 | c.4457G>T p.G1486V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.438); catalogued as rs1353013260, COSV100486864; called by muse, mutect2, varscan2
- COL15A1 | c.3527T>A p.L1176* | Nonsense Mutation (SNP) | VAF 9/176 reads (5%) | catalogued as COSV100898126; called by muse, mutect2
- COL1A2 | c.1448C>A p.A483D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.522); catalogued as rs414408; called by muse, mutect2, varscan2
- COL1A2 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as COSV99801602; called by muse, mutect2, varscan2
- COL22A1 | c.4873G>T p.G1625C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761344086, COSV100276412, COSV100281388; called by muse, mutect2, varscan2
- COL27A1 | c.2806C>T p.P936S | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1334943873, COSV100621422; called by muse, mutect2, varscan2
- COL5A1 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.017); catalogued as COSV100880565, COSV100880753; called by muse, mutect2, varscan2
- COL5A2 | c.1448G>T p.G483V | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100881002, COSV66408865; called by muse, mutect2, varscan2
- CORIN | c.2213C>T p.T738I | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV99904713; called by muse, mutect2, varscan2
- CP | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 31/126 reads (25%) | catalogued as COSV99224583; called by muse, mutect2, varscan2
- CPA1 | c.1082G>T p.S361I | Missense Mutation (SNP) | VAF 110/590 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99163396; called by muse, mutect2, varscan2
- CPB1 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV99294628; called by muse, mutect2, varscan2
- CPNE7 | c.1466C>G p.A489G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs945662312, COSV99254688, COSV99255239; called by muse, mutect2, varscan2
- CPS1 | c.1498C>A p.Q500K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99244512; called by muse, mutect2, varscan2
- CRB1 | c.1527C>A p.N509K | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100958113; called by muse, mutect2, varscan2
- CRB2 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1564371876, COSV100749776; called by muse, mutect2
- CREBBP | c.6903G>A p.M2301I | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99273089; called by muse, mutect2
- CRPPA | c.834G>T p.K278N (on ENST00000407010 / NM_001368197.1; = p.K228N on NM_001101417.4) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101235448; called by muse, mutect2
- CSF1R | c.235A>C p.T79P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99643507; called by muse, mutect2, varscan2
- CSF2RA | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 77/199 reads (39%) | catalogued as COSV100817869, COSV62624372; called by muse, mutect2, varscan2
- CSMD1 | c.7797G>C p.R2599S (on ENST00000520002; = p.R2598S on NM_033225.6) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.572); catalogued as rs767792423, COSV100155396; called by muse, mutect2, varscan2
- CSMD2 | c.7940G>T p.G2647V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.456); catalogued as rs1393828176, COSV99597279; called by muse, mutect2, varscan2
- CSMD3 | c.10171C>T p.R3391C (on ENST00000297405 / NM_001363185.1; = p.R3222C on NM_052900.3) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1216281630, COSV52141744, COSV99849997; called by muse, mutect2, varscan2
- CSMD3 | c.8574A>T p.Q2858H (on ENST00000297405 / NM_001363185.1; = p.Q2689H on NM_052900.3) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99852080; called by muse, mutect2, varscan2
- CSMD3 | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.601); catalogued as COSV99852084; called by muse, mutect2, varscan2
- CSPP1 | c.3367G>T p.V1123F (on ENST00000676605; = p.V1082F on NM_024790.6) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.4); catalogued as COSV51587620, COSV99140326; called by muse, mutect2, varscan2
- CTAGE1 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV101194728; called by muse, mutect2
- CUBN | c.10390C>G p.P3464A | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV100913780; called by muse, mutect2, varscan2
- CWH43 | c.283G>T p.V95F | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.153); catalogued as COSV99894374; called by muse, mutect2, varscan2
- CYLD | c.205C>T p.Q69* | Nonsense Mutation (SNP) | VAF 12/176 reads (7%) | catalogued as COSV100282821; called by muse, mutect2
- CYP11B2 | c.393G>A p.L131= | Splice Region (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100011507; called by muse, mutect2, varscan2
- CYP26B1 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99134419; called by muse, varscan2
- CYP26B1 | c.1054C>A p.R352S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV50013310, COSV99135219; called by muse, varscan2
- CYP27A1 | c.1352G>A p.R451K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV51467954, COSV99298828; called by muse, mutect2, varscan2
- CYP2C18 | c.737A>T p.E246V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV99609101; called by muse, mutect2, varscan2
- CYP2C9 | c.967G>T p.V323F | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99583394; called by muse, mutect2, varscan2
- CYSLTR2 | c.713T>A p.L238Q | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.055); catalogued as COSV99935479; called by muse, mutect2, varscan2
- DACH2 | c.1213C>G p.Q405E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as COSV100914143; called by muse, mutect2
- DCDC1 | c.5270G>T p.R1757L (on ENST00000597505 / NM_001367979.1; = p.R864L on NM_020869.3) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100360872, COSV58003136; called by muse, mutect2, varscan2
- DCHS1 | c.896G>T p.S299I | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100202762; called by muse, mutect2, varscan2
- DDB1 | c.3360G>T p.M1120I | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.033); catalogued as COSV100074493; called by muse, mutect2
- DDX39B | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV100385515; called by muse, mutect2, varscan2
- DDX60 | c.4541T>G p.L1514R | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101190800; called by muse, mutect2, varscan2
- DEFB110 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100953829; called by muse, mutect2
- DENND2C | c.123G>T p.W41C | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.502); catalogued as COSV101283994; called by muse, mutect2, varscan2
- DEPDC7 | c.572C>T p.S191F (on ENST00000241051 / NM_001077242.2; = p.S182F on NM_139160.2) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99572992; called by muse, varscan2
- DGKK | c.3439G>A p.D1147N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV101053286; called by muse, mutect2, varscan2
- DHX35 | c.1403-1G>T p.X468_splice | Splice Site (SNP) | VAF 82/226 reads (36%) | catalogued as COSV99327463; called by muse, mutect2, varscan2
- DHX40 | c.1967C>G p.S656* | Nonsense Mutation (SNP) | VAF 5/59 reads (8%) | catalogued as COSV99233390; called by muse, mutect2
- DHX8 | c.1213-1G>T p.X405_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99292775; called by muse, mutect2, varscan2
- DHX9 | c.1495G>T p.E499* | Nonsense Mutation (SNP) | VAF 16/145 reads (11%) | catalogued as COSV100841565; called by muse, mutect2, varscan2
- DICER1 | c.5552G>T p.R1851L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100602685, COSV58617823; called by muse, mutect2, varscan2
- DIDO1 | c.2777G>A p.R926K | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV56620749; called by muse, mutect2
- DIDO1 | c.1374+1G>T p.X458_splice | Splice Site (SNP) | VAF 64/205 reads (31%) | catalogued as COSV99827656; called by muse, mutect2, varscan2
- DIS3L2 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV99807643; called by muse, mutect2, varscan2
- DLD | c.1390G>T p.V464L | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99227664; called by muse, mutect2, varscan2
- DMD | c.8725G>T p.E2909* | Nonsense Mutation (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100630016; called by muse, mutect2, varscan2
- DMD | c.2479del p.E827Sfs*19 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as rs398123890, CM098383, COSV63739065, COSV63750867, COSV63754448; called by mutect2, pindel, varscan2
- DMD | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99927515; called by muse, varscan2
- DNAH10 | c.11699A>T p.D3900V (on ENST00000409039; = p.D3839V on NM_207437.3) | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101293047; called by muse, mutect2, varscan2
- DNAH11 | c.9226G>A p.E3076K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100181519; called by muse, mutect2, varscan2
- DNAH11 | c.13345C>G p.R4449G | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs751222708, CM157452, COSV100181521; called by muse, mutect2, varscan2
- DNAH3 | c.9397G>C p.E3133Q | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as COSV99771497; called by muse, mutect2
- DNAH5 | c.1089C>T p.P363= | Splice Region (SNP) | VAF 13/81 reads (16%) | catalogued as rs763797137, COSV99443088; called by muse, mutect2, varscan2
- DNAH5 | c.417C>G p.I139M | Missense Mutation (SNP) | VAF 223/421 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV99455822; called by muse, mutect2, varscan2
- DNAH8 | c.1860G>T p.L620F | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.346); catalogued as COSV100547541; called by muse, mutect2
- DNAH9 | c.4909G>T p.A1637S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.392); catalogued as COSV99309036; called by muse, mutect2, varscan2
- DNAJB11 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV99408795; called by muse, mutect2, varscan2
- DNAJC17 | c.681G>T p.A227= | Splice Region (SNP) | VAF 46/203 reads (23%) | catalogued as COSV55024758, COSV99591543; called by muse, mutect2, varscan2
- DOCK7 | c.4183A>G p.K1395E (on ENST00000635253 / NM_001367561.1; = p.K1364E on NM_033407.3) | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV99226548; called by muse, mutect2
- DPEP1 | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV55360762, COSV99878763; called by mutect2, varscan2
- DPH2 | c.1277C>G p.S426* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as COSV99356712; called by muse, mutect2, varscan2
- DPP10 | c.2280C>A p.N760K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as COSV100073421; called by muse, mutect2, varscan2
- DPPA4 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100169807; called by muse, mutect2, varscan2
- DPY19L1 | c.1781G>A p.R594Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764567538, COSV100205153; called by muse, mutect2, varscan2
- DPYD | c.2425G>T p.G809C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929707; called by muse, mutect2, varscan2
- DPYD | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929709; called by muse, mutect2, varscan2
- DPYSL3 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100575479; called by muse, mutect2
- DRD1 | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101192545; called by muse, mutect2, varscan2
- DRD3 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.445); catalogued as COSV99879763; called by muse, mutect2, varscan2
- DRD3 | c.431A>T p.Q144L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV99879764; called by muse, mutect2, varscan2
- DSG1 | c.1402G>C p.D468H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV99936758; called by muse, mutect2, varscan2
- DSP | c.2167C>T p.L723F | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV101131923; called by muse, mutect2
- DTD2 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as COSV100180187; called by muse, mutect2, varscan2
- DYNC1H1 | c.1141G>T p.V381L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as COSV100795634, COSV64137148; called by muse, mutect2, varscan2
- DYNC1I1 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 97/275 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV100269633; called by muse, mutect2, varscan2
- ECM1 | c.642G>T p.E214D | Missense Mutation (SNP) | VAF 85/271 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100682400; called by muse, mutect2, varscan2
- EEFSEC | c.599A>T p.Q200L | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV99631249, COSV99631686; called by muse, mutect2, varscan2
- EGFL8 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 44/239 reads (18%) | catalogued as COSV100247172; called by muse, mutect2, varscan2
- EGFLAM | c.1075G>T p.V359F | Missense Mutation (SNP) | VAF 96/137 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV100380965; called by muse, mutect2, varscan2
- EGFLAM | c.2681T>C p.L894S (on ENST00000354891 / NM_001205301.2; = p.L886S on NM_152403.4) | Missense Mutation (SNP) | VAF 209/306 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1218508624, COSV100380968; called by muse, mutect2, varscan2
- EIF1B | c.54G>C p.K18N | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as COSV99233834; called by muse, mutect2, varscan2
- EIF4A2 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV60623812, COSV60624846; called by muse, mutect2, varscan2
- EMC1 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as COSV100916480, COSV64346415; called by muse, mutect2, varscan2
- EML3 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53883416; called by muse, mutect2, varscan2
- ENGASE | c.1772G>C p.S591T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV100286021; called by muse, mutect2, varscan2
- EPB41L2 | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100441585; called by muse, mutect2, varscan2
- EPHA5 | c.850G>T p.V284L | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99902134; called by muse, mutect2, varscan2
- EPHA7 | c.2161G>T p.A721S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100994506; called by muse, mutect2, varscan2
- EPHB4 | c.95G>T p.W32L | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100639706; called by muse, mutect2, varscan2
- EPHB6 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101236011; called by muse, mutect2, varscan2
- EPHB6 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as COSV101235961, COSV101236012; called by muse, mutect2, varscan2
- EPHB6 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV101236013, COSV67417775; called by muse, mutect2, varscan2
- EPN2 | c.429G>T p.E143D | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100127806; called by muse, mutect2, varscan2
- EPRS1 | c.4408G>C p.G1470R | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as rs765309419, COSV100859559; called by muse, mutect2, varscan2
- ERI3 | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100952295; called by muse, mutect2, varscan2
- ERICH3 | c.3584A>G p.E1195G | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV100446170; called by muse, varscan2
- ESRP1 | c.1775C>T p.P592L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100619766; called by muse, mutect2, varscan2
- ETAA1 | c.1543A>G p.T515A | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.053); catalogued as COSV99713034; called by muse, mutect2, varscan2
- EXPH5 | c.4349G>A p.S1450N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as COSV56202991, COSV56203252; called by muse, mutect2, varscan2
- EYA1 | c.1309C>A p.R437S | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1240529273, COSV100380515, COSV58159391; called by muse, mutect2, varscan2
- EZH2 | c.79A>T p.R27* | Nonsense Mutation (SNP) | VAF 42/225 reads (19%) | catalogued as COSV100237197; called by muse, mutect2, varscan2
- F2 | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61316699, COSV61317614; called by muse, mutect2, varscan2
- F2R | c.1121C>A p.A374D | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100058743; called by muse, mutect2, varscan2
- FAM149A | c.2080C>A p.P694T (on ENST00000356371 / NM_001367768.2; = p.P403T on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV99906819; called by muse, mutect2, varscan2
- FAM161B | c.283G>C p.E95Q (on ENST00000651776; = p.E32Q on NM_152445.3) | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV99474277; called by muse, mutect2
- FAM174A | c.14A>C p.Q5P | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100444705; called by muse, mutect2, varscan2
- FAM193B | c.2005G>T p.A669S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100286917; called by muse, mutect2
- FAM47B | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.711); catalogued as COSV100264758, COSV61452900; called by muse, mutect2, varscan2
- FAM47B | c.1717G>A p.V573I | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as rs1245838847, COSV100264759, COSV61453024; called by muse, mutect2, varscan2
- FAM71A | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54235367, COSV99675001; called by muse, mutect2, varscan2
- FAM83B | c.503A>T p.E168V | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV100175219; called by muse, mutect2, varscan2
- FAM83B | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100175222; called by muse, mutect2, varscan2
- FAM83H | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101187105; called by muse, mutect2
- FBN1 | c.2447G>T p.C816F | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs397515770, CM067402, CM983863, COSV100356701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.6711C>G p.C2237W | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99331678; called by muse, mutect2, varscan2
- FBN3 | c.3806A>G p.Y1269C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99562109; called by muse, mutect2, varscan2
- FBXO40 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100573368; called by muse, mutect2, varscan2
- FCRL3 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 36/160 reads (23%) | catalogued as COSV100943652; called by muse, mutect2, varscan2
- FER | c.2125G>T p.E709* | Nonsense Mutation (SNP) | VAF 5/83 reads (6%) | catalogued as COSV99814294; called by muse, mutect2
- FGD3 | c.1213A>C p.K405Q | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100491048; called by muse, mutect2
- FGD6 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs764358181, COSV100676926; called by muse, mutect2, varscan2
- FGF10 | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.94); catalogued as COSV99241096; called by muse, mutect2, varscan2
- FGF14 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as COSV101088177; called by muse, mutect2, varscan2
- FLG | c.7743G>C p.E2581D | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.084); catalogued as COSV100912475; called by muse, mutect2
- FLG2 | c.6959C>A p.S2320Y | Missense Mutation (SNP) | VAF 96/426 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV101166336; called by muse, mutect2, varscan2
- FLG2 | c.2267C>G p.S756C | Missense Mutation (SNP) | VAF 187/762 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV101166337; called by muse, mutect2, varscan2
- FLG2 | c.1757G>C p.G586A | Missense Mutation (SNP) | VAF 84/710 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV101166338; called by muse, mutect2, varscan2
- FLNC | c.7061C>A p.P2354H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100368428; called by muse, varscan2
- FLT1 | c.2653A>G p.I885V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56722495, COSV99170966; called by muse, mutect2, varscan2
- FOCAD | c.3683G>A p.G1228D | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258802048, COSV100620786; called by muse, mutect2, varscan2
- FOXC2 | c.542C>G p.A181G | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100234441; called by muse, mutect2
- FOXF2 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV99453557; called by muse, mutect2, varscan2
- FPR2 | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV100389508; called by muse, mutect2
- FREM1 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.45); catalogued as COSV66523190; called by muse, mutect2, varscan2
- FREM2 | c.8311G>T p.A2771S | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV54837115, COSV99751648; called by muse, mutect2, varscan2
- FRMPD4 | c.2250C>A p.D750E | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV101044411; called by muse, mutect2, varscan2
- FRS3 | c.155G>C p.R52P | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52486128, COSV99443261; called by muse, mutect2, varscan2
- FSCN2 | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100603377; called by mutect2, varscan2
- FSHR | c.1396G>T p.E466* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100438389; called by muse, mutect2, varscan2
- FTMT | c.466G>T p.G156W | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100360504; called by muse, mutect2, varscan2
- FYCO1 | c.1500G>C p.E500D | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV99946447; called by muse, mutect2
- GABRB1 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99784023; called by muse, mutect2, varscan2
- GABRB3 | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 14/142 reads (10%) | catalogued as COSV100162614; called by muse, mutect2, varscan2
- GAD2 | c.1437G>T p.E479D | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV99394323; called by muse, mutect2, varscan2
- GAL3ST1 | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as rs755783998, COSV100143297; called by muse, mutect2, varscan2
- GALNT3 | c.904G>C p.V302L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765239589, COSV101205035; called by muse, mutect2
- GAS2L2 | c.1776G>T p.L592F | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as rs1250419663; called by muse, mutect2, varscan2
- GBF1 | c.1766C>A p.T589N (on ENST00000369983 / NM_001377137.1; = p.T588N on NM_004193.3) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100890743; called by muse, mutect2, varscan2
- GCC2 | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100565700; called by muse, mutect2, varscan2
- GCN1 | c.2089G>C p.D697H | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs774036141, COSV100326283; called by muse, mutect2, varscan2
- GCNT1 | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946695; called by muse, mutect2, varscan2
- GDI2 | c.1213G>T p.D405Y | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050306, COSV100051250; called by muse, mutect2
- GHDC | c.866C>G p.S289C | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV100055045; called by muse, mutect2
- GK2 | c.641A>T p.E214V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV100726071; called by muse, mutect2
- GLDC | c.789G>C p.L263F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100394751; called by muse, mutect2, varscan2
- GLOD5 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100297563; called by muse, mutect2, varscan2
- GLRA2 | c.203-1G>T p.X68_splice | Splice Site (SNP) | VAF 15/40 reads (38%) | catalogued as COSV99491797; called by muse, mutect2, varscan2
- GLRA2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as COSV99491798; called by muse, mutect2, varscan2
- GNAO1 | c.688G>A p.G230S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.791); catalogued as COSV99341509; called by muse, mutect2, varscan2
- GNAS | c.585+1G>T p.X195_splice | Splice Site (SNP) | VAF 104/277 reads (38%) | catalogued as CS139767, COSV99671249; called by muse, mutect2, varscan2
- GNAT2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV63554878; called by muse, mutect2
- GNPAT | c.743G>C p.R248P | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791737; called by muse, mutect2, varscan2
- GOLGA5 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs150641129; called by muse, mutect2, varscan2
- GOLGA6B | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.486); catalogued as COSV101406970; called by muse, varscan2
- GON4L | c.3700G>A p.A1234T | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV99676235; called by muse, mutect2, varscan2
- GP2 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); catalogued as COSV100221707; called by muse, mutect2, varscan2
- GPATCH8 | c.2031G>C p.K677N | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100132961; called by muse, mutect2, varscan2
- GPC6 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV100990263; called by muse, mutect2, varscan2
- GPR180 | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV100979116; called by muse, mutect2, varscan2
- GPR39 | c.100A>T p.I34F | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs201283876, COSV100258896; called by muse, mutect2, varscan2
- GPR61 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV68177725; called by muse, mutect2
- GPR61 | c.1090C>A p.P364T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.326); catalogued as COSV100880000; called by muse, mutect2, varscan2
- GPR78 | c.475C>A p.R159S | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.121); catalogued as COSV101224053; called by muse, mutect2, varscan2
- GPR85 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV99775355; called by muse, mutect2, varscan2
- GRAMD1A | c.1938G>T p.W646C | Missense Mutation (SNP) | VAF 60/332 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100526509; called by muse, mutect2, varscan2
- GRB14 | c.447G>T p.W149C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV99814691; called by muse, mutect2, varscan2
- GRID2 | c.2776C>A p.H926N | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.775); catalogued as COSV99948473; called by muse, mutect2, varscan2
- GRIK1 | c.829A>C p.M277L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV100518336; called by muse, mutect2, varscan2
- GRIK3 | c.1026G>C p.Q342H | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV100902515; called by muse, mutect2, varscan2
- GRIN2B | c.1673T>A p.V558E | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV101663250; called by muse, mutect2, varscan2
- GRIN2C | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs760630748, COSV99501669; called by muse, mutect2, varscan2
- GRM7 | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1114167301, COSV63138097; called by muse, mutect2
- GRM8 | c.1156+1G>T p.X386_splice | Splice Site (SNP) | VAF 9/60 reads (15%) | catalogued as COSV100286983; called by muse, varscan2
- GSG1 | c.55C>A p.L19I (on ENST00000651961 / NM_001080555.4; = p.L6I on NM_031289.5) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as rs776382474, COSV100189660; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1594G>T p.G532C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV56087302, COSV99735904; called by muse, mutect2, varscan2
- GTF3C1 | c.4948G>T p.G1650C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649847; called by muse, mutect2, varscan2
- GUCY2F | c.3211C>A p.P1071T | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99485926; called by muse, mutect2, varscan2
- GYPA | c.157T>C p.Y53H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.982); catalogued as COSV99303056; called by muse, mutect2, varscan2
- H1-3 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99768567, COSV99768682; called by muse, mutect2, varscan2
- H2AC11 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.029); catalogued as COSV100345936, COSV60362363; called by muse, mutect2, varscan2
- H2AC20 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58613363; called by muse, mutect2
- H2BC4 | c.169T>A p.S57T | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100020143; called by muse, mutect2, varscan2
- H3C11 | c.377A>T p.Q126L | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.693); catalogued as COSV100138154; called by muse, mutect2, varscan2
- H4C7 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV99769332; called by muse, mutect2, varscan2
- HAS2 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as COSV100392304; called by muse, mutect2, varscan2
- HAUS3 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV54721808, COSV99704165; called by muse, mutect2, varscan2
- HCAR1 | c.583T>A p.C195S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100811904; called by muse, mutect2, varscan2
- HECW1 | c.4338G>A p.W1446* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV101224431; called by muse, mutect2, varscan2
- HEPHL1 | c.427C>G p.P143A | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100244637; called by muse, mutect2, varscan2
- HERC1 | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV101497112; called by muse, mutect2
- HERC4 | c.484G>T p.G162* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as COSV99517693; called by muse, mutect2, varscan2
- HHIPL2 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.405); catalogued as COSV100597182; called by muse, mutect2, varscan2
- HIP1 | c.2696A>T p.K899I | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100418286; called by muse, mutect2
- HIP1 | c.2645G>T p.G882V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61191593; called by muse, mutect2, varscan2
- HIRIP3 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.212); catalogued as COSV99663434; called by muse, mutect2, varscan2
- HIVEP3 | c.2685G>T p.Q895H | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99914377; called by muse, mutect2, varscan2
- HMGB1 | c.46T>A p.Y16N | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV100361061; called by muse, mutect2
- HNRNPU | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99310817; called by muse, mutect2, varscan2
- HOXA1 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as CD082131, COSV99761529; called by muse, mutect2, varscan2
- HPSE2 | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs1159451933, COSV100986390; called by muse, mutect2, varscan2
- HRNR | c.1003C>A p.R335S | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100914064, COSV64258916; called by muse, mutect2, varscan2
- HSPA13 | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 9/177 reads (5%) | catalogued as COSV53466951; called by muse, mutect2
- HSPA6 | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV100554400; called by muse, mutect2, varscan2
- HTRA1 | c.636T>A p.D212E | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV100934840; called by muse, mutect2, varscan2
- HUWE1 | c.2248G>C p.E750Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.025); catalogued as COSV99474987; called by muse, mutect2, varscan2
- HYAL4 | c.491G>T p.R164I | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99772557; called by muse, mutect2
- HYDIN | c.6802C>A p.Q2268K | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV99994072; called by muse, mutect2
- IARS2 | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV56962814, COSV56963514; called by muse, mutect2, varscan2
- IFNAR2 | c.818G>C p.R273T | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100577183; called by muse, mutect2
- IFT140 | c.3391G>T p.D1131Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV100794573; called by muse, mutect2, varscan2
- IFT172 | c.2584dup p.D862Gfs*10 | Frame Shift Ins (INS) | VAF 32/231 reads (14%) | catalogued as rs1489674192; called by mutect2, varscan2
- IFT20 | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99880838; called by muse, mutect2
- IFT80 | c.2294C>G p.S765* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100425233, COSV58446297; called by muse, mutect2, varscan2
- IGDCC3 | c.2356C>A p.P786T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV100031651; called by muse, mutect2, varscan2
- IGF2R | c.1295T>G p.F432C | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100808427; called by muse, mutect2, varscan2
- IGFL1 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV101473080; called by muse, mutect2, varscan2
- IGFL4 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs993918202, COSV66618979; called by muse, mutect2, varscan2
- IGHV3-21 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.068); catalogued as rs782181793; called by muse, mutect2, varscan2
- IGHV5-51 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs113154616; called by muse, mutect2, varscan2
- IKZF1 | c.1374G>C p.Q458H | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.367); catalogued as COSV58785581; called by muse, mutect2
- IL17F | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100277329; called by muse, mutect2, varscan2
- IL22RA2 | c.150del p.R51Gfs*22 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | catalogued as COSV51662658; called by mutect2, pindel, varscan2
- IL31RA | c.2233G>C p.V745L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV100732433, COSV100732982; called by muse, mutect2
- INF2 | c.3644C>T p.S1215L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99384629; called by muse, mutect2, varscan2
- INTS12 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV100415969; called by muse, mutect2
- INTS6L | c.499A>T p.R167W | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100878173; called by muse, mutect2, varscan2
- IQCF1 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100095022; called by muse, mutect2, varscan2
- IQGAP2 | c.1577A>T p.D526V | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99169337; called by muse, mutect2, varscan2
- IQGAP3 | c.4673+1G>T p.X1558_splice | Splice Site (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100752487; called by muse, mutect2, varscan2
- IQUB | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 15/129 reads (12%) | catalogued as COSV100227462, COSV61238675; called by muse, mutect2, varscan2
- IRAK2 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99844442; called by muse, mutect2, varscan2
- IRX3 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100315452; called by muse, mutect2
- ISOC1 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as COSV99434792; called by mutect2, varscan2
- ITGAD | c.1733C>A p.P578H | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV101210641; called by muse, mutect2, varscan2
- ITGAX | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99191603; called by muse, mutect2, varscan2
- ITPKC | c.1977G>T p.E659D | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV99648835; called by muse, mutect2, varscan2
- IZUMO1R | c.94C>A p.H32N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.913); catalogued as COSV100126960; called by muse, mutect2, varscan2
- JAG1 | c.1329G>T p.M443I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99653648; called by muse, mutect2, varscan2
- JAKMIP2 | c.1225-2A>T p.X409_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99509549; called by muse, mutect2, varscan2
- JAKMIP2 | c.23A>T p.K8M | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99509552; called by muse, mutect2, varscan2
- JHY | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1008104966, COSV56220426, COSV56221804; called by muse, mutect2, varscan2
- KALRN | c.8449G>T p.V2817L (on ENST00000360013 / NM_001024660.4; = p.V1120L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.981); catalogued as COSV99363281; called by muse, mutect2, varscan2
- KATNA1 | c.1409C>G p.S470C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as COSV59501405; called by muse, mutect2
- KATNB1 | c.1805C>A p.S602Y | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65551877; called by muse, mutect2
- KCNB2 | c.1598A>T p.Q533L | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101579046; called by muse, mutect2, varscan2
- KCNH1 | c.2111G>T p.R704M (on ENST00000271751 / NM_172362.3; = p.R677M on NM_002238.4) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55080216; called by muse, mutect2
- KCNH5 | c.2733G>T p.Q911H | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); catalogued as COSV100528562; called by muse, mutect2, varscan2
- KCNH8 | c.1486G>T p.V496F | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.795); catalogued as COSV100111263; called by muse, mutect2, varscan2
- KCNIP3 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); catalogued as COSV99734728; called by muse, mutect2, varscan2
- KCNJ1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.45); catalogued as COSV100131550; called by muse, mutect2, varscan2
- KCNJ1 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV60661541; called by muse, mutect2
- KCNJ3 | c.946T>A p.Y316N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54546645, COSV99716673; called by muse, mutect2, varscan2
- KCNK3 | c.331A>T p.M111L | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100257302; called by muse, mutect2, varscan2
- KCNK3 | c.676G>T p.V226F | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV100257305, COSV57193111; called by muse, mutect2, varscan2
- KCTD10 | c.836C>A p.A279E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as COSV57326943, COSV99949496; called by muse, mutect2, varscan2
- KCTD13 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774531778, COSV100442022; called by muse, mutect2, varscan2
- KDM5B | c.4498-2A>T p.X1500_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99351661; called by muse, mutect2, varscan2
- KDM6B | c.886G>T p.G296C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.236); catalogued as COSV99642563; called by muse, mutect2, varscan2
- KIDINS220 | c.5273C>G p.S1758C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99876643; called by muse, mutect2
- KIDINS220 | c.1345G>T p.D449Y | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876645; called by muse, mutect2
- KIF13B | c.3628G>T p.E1210* | Nonsense Mutation (SNP) | VAF 24/93 reads (26%) | catalogued as COSV101580893; called by muse, mutect2, varscan2
- KIF20B | c.3038C>G p.S1013* (on ENST00000371728 / NM_001284259.2; = p.S973* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | catalogued as COSV99590931; called by muse, mutect2, varscan2
- KIF24 | c.3472G>A p.E1158K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV99903692; called by muse, mutect2, varscan2
- KIF2B | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs377704600; called by muse, mutect2, varscan2
- KIN | c.883G>T p.G295* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV101092735, COSV65430052; called by muse, mutect2, varscan2
- KIR3DL2 | c.1181A>T p.Q394L | Missense Mutation (SNP) | VAF 150/439 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99552444; called by muse, mutect2, varscan2
- KLB | c.2668A>G p.S890G | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV99962574; called by muse, mutect2, varscan2
- KLHL1 | c.1522C>G p.L508V | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100918422, COSV64776087; called by muse, mutect2, varscan2
- KLHL1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.194); catalogued as rs754998896, COSV64781118; called by muse, mutect2
- KLHL23 | c.690A>G p.I230M | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs775191350, COSV99776220; called by muse, mutect2, varscan2
- KLK2 | c.650T>G p.L217R | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100320097; called by muse, mutect2
- KLK7 | c.677G>A p.C226Y | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754525282, COSV100304365; called by muse, mutect2, varscan2
- KLRB1 | c.183A>T p.S61= | Splice Region (SNP) | VAF 18/43 reads (42%) | catalogued as COSV99987370; called by muse, mutect2, varscan2
- KLRC1 | c.353A>T p.H118L | Missense Mutation (SNP) | VAF 144/303 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV100760934; called by muse, mutect2, varscan2
- KLRF1 | c.587+1G>A p.X196_splice | Splice Site (SNP) | VAF 13/72 reads (18%) | catalogued as COSV54382004, COSV99684589; called by muse, mutect2
- KMT2C | c.9046C>T p.Q3016* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV100078469, COSV51486122; called by muse, mutect2, varscan2
- KRT19 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs780656229, COSV99563397; called by muse, mutect2
- KRT40 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100898930, COSV66696564; called by muse, mutect2, varscan2
- KRT6B | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV99361133; called by muse, mutect2, varscan2
- KRT71 | c.584T>A p.L195Q | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV99922462; called by muse, mutect2, varscan2
- LAMA1 | c.9220G>T p.E3074* | Nonsense Mutation (SNP) | VAF 47/182 reads (26%) | catalogued as COSV101058098; called by muse, mutect2, varscan2
- LAMA1 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101058100; called by muse, mutect2, varscan2
- LAMA2 | c.4688G>T p.W1563L | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV101370967; called by muse, mutect2, varscan2
- LAMA4 | c.3667G>T p.V1223F (on ENST00000230538 / NM_001105206.3; = p.V1216F on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs781868927, COSV100039893; called by muse, mutect2, varscan2
- LAMB4 | c.3916G>T p.D1306Y | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99226168; called by muse, mutect2, varscan2
- LAMP3 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV55617047, COSV99660865; called by muse, mutect2, varscan2
- LAMP3 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99660866; called by muse, mutect2, varscan2
- LAPTM5 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV99612731; called by muse, mutect2, varscan2
- LAT | c.319G>T p.V107L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV100209389; called by muse, mutect2, varscan2
- LCE1E | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (1); catalogued as COSV100908586; called by muse, varscan2
- LCP1 | c.1209G>T p.W403C | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100550145; called by muse, mutect2
- LHX3 | c.642G>T p.R214S (on ENST00000371748 / NM_178138.6; = p.R219S on NM_014564.5) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV100871315; called by muse, mutect2, varscan2
- LIFR | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as COSV99665862; called by muse, mutect2, varscan2
- LOXL3 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99240040; called by muse, mutect2
- LPA | c.4669G>T p.G1557W | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV100308382; called by muse, mutect2, varscan2
- LPAR4 | c.418A>T p.I140F | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101425185; called by muse, mutect2, varscan2
- LPIN1 | c.1148G>T p.R383M | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99878406; called by muse, mutect2, varscan2
- LPIN1 | c.1149G>T p.R383S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.206); catalogued as COSV56770514; called by muse, mutect2, varscan2
- LRAT | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100311995; called by muse, mutect2, varscan2
- LRIT2 | c.662C>A p.P221Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100259501; called by muse, mutect2
- LRP1 | c.3992-1G>T p.X1331_splice | Splice Site (SNP) | VAF 10/105 reads (10%) | catalogued as COSV99677907; called by muse, mutect2, varscan2
- LRP1B | c.13510C>A p.H4504N | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV101262207; called by muse, mutect2, varscan2
- LRP2 | c.2683G>T p.E895* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | catalogued as COSV55582509, COSV99790868; called by muse, mutect2, varscan2
- LRP4 | c.4831C>A p.Q1611K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs185325829, COSV101066969; called by muse, mutect2, varscan2
- LRP5 | c.1405G>T p.V469L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99592863; called by muse, mutect2, varscan2
- LRR1 | c.278G>A p.S93N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV100023331; called by muse, mutect2, varscan2
- LRRC4B | c.1522G>T p.G508W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.206); catalogued as COSV100976094; called by muse, mutect2, varscan2
- LRRC4C | c.1574C>T p.T525I | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99540330; called by muse, mutect2, varscan2
- LRRIQ1 | c.1206G>C p.K402N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV101280776; called by muse, mutect2, varscan2
- LRRIQ1 | c.1958G>A p.S653N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.153); catalogued as rs370634801, COSV101280777; called by muse, mutect2, varscan2
- LRRTM3 | c.756G>A p.W252* | Nonsense Mutation (SNP) | VAF 8/146 reads (5%) | catalogued as COSV100791980; called by muse, mutect2
- LSAMP | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100373449; called by muse, mutect2, varscan2
- LTN1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100798317; called by muse, mutect2, varscan2
- LVRN | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100773727; called by muse, mutect2, varscan2
- MACC1 | c.2398G>T p.G800* | Nonsense Mutation (SNP) | VAF 47/142 reads (33%) | catalogued as COSV100256406; called by muse, varscan2
- MAEL | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774772; called by muse, mutect2, varscan2
- MAGEA3 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV64755890; called by muse, mutect2, varscan2
- MAMDC2 | c.921C>G p.F307L | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV101016002; called by muse, mutect2
- MAP1B | c.4462C>T p.P1488S | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99703089; called by muse, mutect2, varscan2
- MAP1S | c.1795G>T p.G599C | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as rs759144600, COSV100141345; called by muse, varscan2
- MAP3K19 | c.3178C>A p.L1060I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV59640773; called by muse, mutect2, varscan2
- MAP3K19 | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100209064, COSV100209511, COSV59638494; called by muse, mutect2
- MAST2 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs752868391, COSV63620693; called by mutect2, varscan2
- MAST2 | c.4021A>T p.I1341F | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV100788957; called by muse, mutect2, varscan2
- MBTPS1 | c.2065C>G p.Q689E | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as rs1480633932, COSV100597918; called by muse, mutect2, varscan2
- MCHR2 | c.719G>T p.S240I | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV99912903; called by muse, mutect2, varscan2
- ME2 | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.485); catalogued as COSV100361045; called by muse, mutect2, varscan2
- MEGF6 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV99621646; called by muse, mutect2, varscan2
- METTL22 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99372002; called by muse, mutect2, varscan2
- MEX3A | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV68478995, COSV68479139; called by muse, mutect2
- MFN2 | c.725A>T p.H242L | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99337203; called by muse, mutect2, varscan2
- MGAM | c.303C>A p.C101* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV71885223; called by muse, mutect2, varscan2
- MGAT3 | c.1240T>G p.F414V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV100362121; called by muse, varscan2
- MGAT4B | c.663C>G p.F221L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99482481; called by muse, mutect2
- MIB1 | c.3005G>T p.R1002M | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99839685; called by muse, mutect2, varscan2
- MICU3 | c.472G>C p.E158Q | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); catalogued as COSV100536682; called by muse, mutect2, varscan2
- MKRN3 | c.989G>C p.G330A | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100091841; called by muse, mutect2, varscan2
- MMP1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100188147, COSV59510400; called by muse, mutect2, varscan2
- MMP12 | c.428A>C p.N143T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV100405134; called by muse, mutect2, varscan2
- MMS22L | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99247940; called by muse, mutect2
- MORC1 | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99228281; called by muse, mutect2, varscan2
- MORF4L1 | c.550G>T p.E184* (on ENST00000331268 / NM_206839.2; = p.E145* on NM_006791.4) | Nonsense Mutation (SNP) | VAF 18/53 reads (34%) | catalogued as COSV58703690, COSV58704180; called by muse, mutect2, varscan2
- MORN5 | c.334C>A p.P112T | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101056033; called by muse, mutect2, varscan2
- MPHOSPH10 | c.693G>T p.E231D | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.111); catalogued as COSV99731373; called by muse, mutect2, varscan2
- MRPL3 | c.569-1G>A p.X190_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99394929, COSV99395131; called by muse, mutect2
- MRPL57 | c.11C>T p.T4I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as rs756534195, COSV100006607, COSV53434551; called by muse, mutect2, varscan2
- MRPS36 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.031); catalogued as COSV99841139; called by muse, mutect2
- MS4A6A | c.523T>A p.C175S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100125172; called by muse, mutect2, varscan2
- MSH4 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV99592893; called by muse, mutect2
- MTF1 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100886680; called by muse, mutect2, varscan2
- MTHFS | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99358040; called by muse, mutect2, varscan2
- MTMR1 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV100954199; called by muse, mutect2, varscan2
- MTMR9 | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs1400126061, COSV99644697; called by muse, mutect2, varscan2
- MTNR1B | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV99925438; called by muse, mutect2, varscan2
- MTOR | c.4465G>T p.E1489* | Nonsense Mutation (SNP) | VAF 60/239 reads (25%) | catalogued as COSV100816827; called by muse, mutect2, varscan2
- MTSS1 | c.1859C>A p.T620N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99413034; called by muse, mutect2, varscan2
- MUC16 | c.14918C>T p.T4973I | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV101202316; called by muse, mutect2, varscan2
- MUC16 | c.14239T>A p.S4747T | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.859); catalogued as COSV101202317; called by muse, mutect2, varscan2
- MUC17 | c.7040C>T p.T2347I | Missense Mutation (SNP) | VAF 175/494 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.351); catalogued as COSV100075680; called by muse, mutect2, varscan2
- MUC6 | c.6893C>G p.S2298C | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100173457; called by muse, mutect2
- MVB12A | c.315G>T p.M105I | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100396650; called by muse, mutect2, varscan2
- MXRA5 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.446); catalogued as rs777696915, COSV99479901; called by muse, mutect2, varscan2
- MYBL1 | c.1456T>C p.F486L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV72919180; called by muse, mutect2, varscan2
- MYF5 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.686); catalogued as rs867196870, COSV57354909, COSV99953460; called by muse, varscan2
- MYH1 | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV99877273; called by muse, mutect2
- MYH13 | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99355618; called by muse, mutect2, varscan2
- MYH3 | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56863701; called by muse, mutect2
- MYH7 | c.3502G>A p.E1168K | Missense Mutation (SNP) | VAF 4/77 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1566527832, COSV62524598; ClinVar: uncertain significance; called by muse, mutect2
- MYH8 | c.2424G>T p.L808F | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV101239021; called by muse, mutect2, varscan2
- MYH8 | c.946G>T p.V316F | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV101239022, COSV67970574; called by muse, mutect2, varscan2
- MYO18B | c.5704G>A p.D1902N | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59140474; called by muse, mutect2, varscan2
- MYO1C | c.1787G>T p.R596L (on ENST00000648651 / NM_001080779.2; = p.R561L on NM_033375.5) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs372299065; called by muse, mutect2, varscan2
- MYO1E | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs766788690, COSV99896941; called by muse, mutect2, varscan2
- MYPN | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV100590793; called by muse, mutect2, varscan2
- MYT1L | c.2476C>A p.P826T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.184); catalogued as COSV101221596; called by muse, mutect2, varscan2
- N4BP1 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99285736; called by muse, mutect2
- NAALADL2 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV101435804; called by muse, mutect2, varscan2
- NALCN | c.1379G>T p.G460V | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99218623; called by muse, mutect2, varscan2
- NANOG | c.417G>A p.V139= | Splice Region (SNP) | VAF 5/27 reads (19%) | catalogued as COSV57550973, COSV99981802; called by muse, mutect2, varscan2
- NAP1L3 | c.425C>G p.P142R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100220779; called by muse, mutect2, varscan2
- NAP1L3 | c.314G>C p.R105T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as COSV100220221, COSV100220781; called by muse, mutect2
- NAPSA | c.780C>G p.I260M | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99516039; called by muse, mutect2
- NBEAL1 | c.5248G>A p.A1750T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1243367627, COSV101495825; called by muse, mutect2, varscan2
- NCAPG | c.558G>C p.L186F | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV99266272; called by muse, mutect2
- NCAPG | c.2704G>C p.G902R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52272677; called by muse, mutect2, varscan2
- NCAPG2 | c.1762G>C p.E588Q | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV99317775; called by muse, mutect2, varscan2
- NCOA1 | c.2996C>T p.S999F | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as rs1049032, COSV99947407; called by muse, mutect2, varscan2
- NCOA3 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV59068196; called by muse, mutect2
- NCOA6 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100750465, COSV62862902; called by muse, mutect2, varscan2
- NDST3 | c.1342A>T p.S448C | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99632330; called by muse, mutect2, varscan2
- NDST4 | c.1434G>C p.L478F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99998416; called by muse, mutect2, varscan2
- NEB | c.5890C>A p.P1964T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51431335, COSV99429330; called by muse, mutect2, varscan2
- NEK7 | c.58-1G>T p.X20_splice | Splice Site (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100954518, COSV66311627; called by muse, mutect2, varscan2
- NELL2 | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.541); catalogued as COSV100421242; called by muse, mutect2, varscan2
- NEO1 | c.2231C>G p.S744C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99983017; called by muse, mutect2, varscan2
- NETO1 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.915); catalogued as COSV100199944; called by muse, mutect2, varscan2
- NF2 | c.1112A>T p.N371I | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100099874, COSV58528596; called by muse, mutect2, varscan2
- NFIC | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59415738; called by muse, mutect2, varscan2
- NFIX | c.936G>T p.W312C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100666690; called by muse, mutect2, varscan2
- NFKBIA | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99395425; called by muse, mutect2, varscan2
- NGFR | c.484del p.D162Tfs*63 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as COSV50803988; called by mutect2, pindel
- NID1 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.321); catalogued as COSV99938503; called by muse, mutect2, varscan2
- NKX2-2 | c.145G>T p.G49W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV65819557; called by muse, mutect2, varscan2
- NLGN4Y | c.1536C>G p.F512L | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV100197270; called by muse, mutect2
- NLRP10 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 9/128 reads (7%) | catalogued as COSV100149438, COSV100150045, COSV60780417; called by muse, mutect2
- NLRP13 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100738237, COSV100738685; called by muse, mutect2
- NLRP4 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56708423; called by muse, mutect2
- NLRP5 | c.1957C>G p.L653V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV101173974, COSV101174004; called by muse, mutect2
- NLRP5 | c.2187C>A p.H729Q | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.542); catalogued as COSV101174005; called by muse, mutect2, varscan2
- NLRP7 | c.2555G>C p.C852S (on ENST00000340844 / NM_206828.3; = p.C824S on NM_139176.3) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.042); catalogued as COSV100053537; called by muse, mutect2, varscan2
- NOC2L | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV100498242; called by muse, mutect2
- NOP10 | c.173A>T p.Q58L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100182467; called by muse, mutect2, varscan2
- NOS3 | c.1546A>T p.K516* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV99872392; called by muse, mutect2, varscan2
- NOTCH2 | c.5374C>T p.Q1792* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | catalogued as COSV56701651; called by muse, mutect2, varscan2
- NOVA1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 40/155 reads (26%) | catalogued as COSV99949050; called by muse, mutect2, varscan2
- NPAP1 | c.1289C>A p.A430D | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV100276411; called by muse, mutect2, varscan2
- NPAS3 | c.1351C>A p.L451M (on ENST00000356141 / NM_001164749.2; = p.L419M on NM_022123.3) | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV100640837; called by muse, mutect2, varscan2
- NPHP3 | c.2194G>C p.D732H | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV100447492; called by muse, mutect2
- NPY5R | c.893C>G p.P298R | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100642993; called by muse, mutect2
- NR5A2 | c.309T>G p.C103W (on ENST00000367362 / NM_205860.3; = p.C57W on NM_003822.5) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99371852; called by muse, mutect2, varscan2
- NRAP | c.2216C>G p.A739G (on ENST00000359988 / NM_001322945.2; = p.A704G on NM_006175.4) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100748410; called by muse, mutect2, varscan2
- NRBP1 | c.1499G>T p.S500I | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as COSV99275385; called by muse, mutect2, varscan2
- NRROS | c.1083G>T p.Q361H | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100145679; called by muse, mutect2, varscan2
- NRXN1 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); catalogued as rs781319797, COSV58452486; called by muse, mutect2, varscan2
- NRXN1 | c.1001C>A p.A334D | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100457699; called by muse, mutect2, varscan2
- NSD1 | c.6082G>A p.E2028K | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100729955, COSV61785758; called by muse, mutect2
- NT5E | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100004463; called by muse, mutect2, varscan2
- NTRK2 | c.1833C>A p.D611E (on ENST00000323115 / NM_001369534.1; = p.D627E on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.979); catalogued as COSV99459439; called by muse, mutect2, varscan2
- NUP155 | c.960G>C p.Q320H (on ENST00000231498 / NM_153485.3; = p.Q261H on NM_004298.4) | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.566); catalogued as COSV99195653; called by muse, mutect2
- NUP58 | c.15C>G p.F5L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.916); catalogued as COSV101098955; called by muse, mutect2, varscan2
- NYAP2 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99799055; called by muse, mutect2
- OCEL1 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as rs922843400, COSV99285857; called by muse, mutect2
- OIT3 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs184800341, COSV100468455; called by muse, mutect2, varscan2
- OR10G9 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100901516; called by muse, mutect2, varscan2
- OR10J3 | c.604G>T p.V202F | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.111); catalogued as rs1207041682, COSV100171941; called by muse, mutect2, varscan2
- OR10K2 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100149729; called by muse, mutect2, varscan2
- OR10K2 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs761825468, COSV100149731; called by muse, mutect2, varscan2
- OR13C8 | c.339G>C p.M113I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100623048, COSV58611198, COSV58611995; called by muse, mutect2, varscan2
- OR13F1 | c.274A>G p.I92V | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV100594900; called by muse, mutect2, varscan2
- OR14J1 | c.448G>T p.G150W | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101012895; called by muse, mutect2, varscan2
- OR14K1 | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99315573; called by muse, mutect2
- OR1L6 | c.869G>T p.G290V (on ENST00000373684; = p.G254V on NM_001004453.2) | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100491041; called by muse, mutect2, varscan2
- OR2A2 | c.917G>A p.R306K | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs766933778, COSV101286692; called by muse, mutect2, varscan2
- OR2AK2 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as rs759600821, COSV100824420; called by muse, mutect2
- OR2B11 | c.575C>G p.S192W | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100275908, COSV100276857; called by muse, mutect2, varscan2
- OR2C1 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.17); catalogued as COSV100515081; called by muse, mutect2
- OR2L2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 29/329 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV100824421; called by muse, mutect2
- OR2L8 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV100594380; called by muse, mutect2, varscan2
- OR2T12 | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100527596, COSV100528078; called by muse, mutect2, varscan2
- OR4A5 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); catalogued as COSV60523615, COSV60523768; called by muse, mutect2, varscan2
- OR4C15 | c.137G>C p.G46A | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100116186, COSV100116216; called by muse, mutect2
- OR4C46 | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV100061111; called by muse, mutect2, varscan2
- OR4D10 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101597040; called by muse, mutect2, varscan2
- OR4S2 | c.164C>A p.S55* | Nonsense Mutation (SNP) | VAF 36/187 reads (19%) | catalogued as COSV100412876, COSV56748672; called by muse, mutect2, varscan2
- OR51B2 | c.500G>T p.C167F | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100173586; called by muse, mutect2
- OR51E2 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV101211417; called by muse, mutect2, varscan2
- OR51T1 | c.814A>G p.R272G | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV100434524, COSV59023535; called by muse, mutect2
- OR52B6 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV100798566; called by muse, mutect2, varscan2
- OR52I2 | c.776C>A p.S259Y | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100443048; called by muse, mutect2
- OR52N5 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV100399806; called by muse, mutect2, varscan2
- OR56B1 | c.932T>A p.F311Y | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs1275152845, COSV100402761; called by muse, mutect2
- OR5AP2 | c.876T>A p.N292K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100266503, COSV57259607; called by muse, mutect2, varscan2
- OR5AP2 | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100266504; called by muse, mutect2, varscan2
- OR5B12 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV100222614; called by muse, mutect2, varscan2
- OR5D13 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.255); catalogued as rs761562338, COSV100686644; called by muse, mutect2, varscan2
- OR5D14 | c.423G>T p.R141S | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV100162696; called by muse, mutect2, varscan2
- OR5K1 | c.723T>A p.C241* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | catalogued as COSV100221075; called by muse, mutect2
- OR5L2 | c.646A>C p.T216P | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV101004451; called by muse, mutect2, varscan2
- OR5W2 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100747792; called by muse, mutect2
- OR6Q1 | c.334G>C p.G112R | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100110718; called by muse, mutect2, varscan2
- OR6Q1 | c.686T>C p.L229P | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100110722; called by muse, mutect2, varscan2
- OR8A1 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.179); catalogued as COSV99420950; called by muse, mutect2
- OR8B3 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); catalogued as COSV100660453; called by muse, mutect2, varscan2
- OR8D2 | c.773T>C p.M258T | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV100659149; called by muse, varscan2
- OR8D2 | c.702A>T p.Q234H | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV100659137, COSV100659151; called by muse, varscan2
- OR8D4 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 52/234 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV58430980; called by muse, mutect2, varscan2
- OR8H1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 61/321 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV100477459; called by muse, mutect2, varscan2
- OR8H3 | c.785C>G p.P262R | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100539199, COSV57911683; called by muse, mutect2, varscan2
- OR8K1 | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV54402096; called by muse, mutect2, varscan2
- OR8U1 | c.865A>T p.I289F | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100164189; called by muse, varscan2
- OS9 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV99233223; called by muse, mutect2
- OTOA | c.282C>A p.N94K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV99626186; called by muse, mutect2, varscan2
- OTOL1 | c.499G>T p.G167* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as rs760377334, COSV100020338; called by muse, mutect2, varscan2
- OTUD7A | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100193461, COSV61044373; called by muse, mutect2, varscan2
- OXGR1 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV100037174; called by muse, mutect2, varscan2
- P3H2 | c.481-1G>C p.X161_splice | Splice Site (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100078762; called by mutect2, varscan2
- P4HA2 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.416); catalogued as COSV99387593; called by muse, mutect2, varscan2
- P4HA3 | c.1240A>T p.T414S | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV100525975; called by muse, mutect2
- P4HB | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100515962; called by muse, mutect2
- PABPC4 | c.751A>G p.M251V | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as COSV100790948; called by muse, mutect2
- PAK5 | c.1577T>C p.L526P | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100781810; called by muse, mutect2, varscan2
- PANX3 | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99421198; called by muse, mutect2, varscan2
- PAPPA2 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs749472884, COSV100867290; called by muse, mutect2, varscan2
- PAPPA2 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100867293; called by muse, mutect2, varscan2
- PAPPA2 | c.4906G>T p.E1636* | Nonsense Mutation (SNP) | VAF 13/62 reads (21%) | catalogued as COSV100868870; called by muse, mutect2, varscan2
- PAPSS2 | c.1200G>A p.M400I | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100753730; called by muse, mutect2
- PASD1 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100949743; called by muse, mutect2, varscan2
- PAX1 | c.698C>A p.P233Q | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.189); catalogued as COSV68272749; called by muse, mutect2, varscan2
- PAXX | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100860494; called by muse, mutect2, varscan2
- PBLD | c.824G>A p.R275K | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV99516282; called by muse, mutect2, varscan2
- PCDH1 | c.3103G>A p.G1035S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.041); catalogued as COSV99747223; called by muse, mutect2
- PCDH11X | c.1712C>A p.T571N | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53475571; called by muse, mutect2, varscan2
- PCDH11X | c.1975G>A p.V659I | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as rs1181226724, COSV100007759; called by muse, mutect2, varscan2
- PCDH11X | c.3320A>T p.D1107V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100016417; called by mutect2, varscan2
- PCDH15 | c.4613G>T p.G1538V (on ENST00000644397 / NM_001354429.2; = p.G1487V on NM_001142769.3) | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.989); catalogued as rs866521047, COSV100906024; called by muse, mutect2, varscan2
- PCDH15 | c.3494G>A p.R1165K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.013); catalogued as COSV100213245, COSV100229870; called by muse, mutect2, varscan2
- PCDH15 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV100229874, COSV57382459; called by muse, mutect2, varscan2
- PCDH17 | c.616C>G p.Q206E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV100932225; called by muse, mutect2, varscan2
- PCDHA12 | c.1543G>T p.G515C | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs371309003, COSV56553142; called by muse, mutect2, varscan2
- PCDHA4 | c.2356C>A p.L786M | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as COSV100793867; called by muse, mutect2, varscan2
- PCDHA9 | c.1852G>T p.A618S | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as COSV100970248, COSV65329311; called by muse, mutect2, varscan2
- PCDHA9 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as rs1554144905, COSV100970249; called by muse, mutect2
- PCDHAC2 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99163961; called by muse, mutect2, varscan2
- PCDHB11 | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.336); catalogued as rs1322914499, COSV61313487; called by muse, mutect2
- PCDHB2 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.117); catalogued as COSV99167230; called by muse, mutect2, varscan2
- PCDHB4 | c.1919T>C p.V640A | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs782135352, COSV52028113; called by muse, mutect2, varscan2
- PCDHGA2 | c.2095G>T p.A699S | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.082); catalogued as COSV99549912; called by muse, mutect2, varscan2
- PCDHGA2 | c.2329G>T p.D777Y | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV99549916; called by muse, mutect2
- PCDHGA8 | c.2050C>A p.P684T | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV53914913, COSV99549920; called by muse, mutect2, varscan2
- PCDHGA9 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99549921; called by muse, mutect2, varscan2
- PCDHGC5 | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99342692, COSV99343147; called by muse, mutect2, varscan2
- PCLO | c.5777A>G p.H1926R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as COSV100439666; called by muse, mutect2, varscan2
- PCSK5 | c.1165G>C p.A389P | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100950866; called by muse, mutect2, varscan2
- PCSK9 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs554488891, COSV100135681; called by muse, varscan2
- PDE4B | c.1764G>C p.Q588H | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100305694; called by muse, mutect2
- PDGFD | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.368); catalogued as rs771409365, COSV100161347; called by muse, mutect2, varscan2
- PDGFRA | c.2359T>A p.S787T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV99958052; called by muse, mutect2
- PDLIM3 | c.268C>T p.Q90* (on ENST00000284770 / NM_001257963.1; = p.Q257* on NM_014476.6) | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99507960; called by muse, mutect2, varscan2
- PDLIM7 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV100730362; called by muse, mutect2, varscan2
- PDZRN4 | c.2257G>C p.D753H (on ENST00000402685 / NM_001164595.2; = p.D495H on NM_013377.4) | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100115867; called by muse, mutect2
- PEAR1 | c.1769C>T p.P590L | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52771677, COSV52776301; called by muse, mutect2, varscan2
- PGBD2 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 29/107 reads (27%) | catalogued as COSV100252314; called by muse, mutect2, varscan2
- PHF3 | c.4327C>T p.L1443F | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778125792, COSV100014220; called by muse, mutect2, varscan2
- PHF8 | c.1201G>C p.E401Q (on ENST00000357988 / NM_001184896.1; = p.E365Q on NM_015107.3) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100155123; called by muse, mutect2, varscan2
- PHKB | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.208); catalogued as COSV100068968, COSV54524840; called by muse, mutect2, varscan2
- PIK3C2B | c.2346G>T p.Q782H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100916269, COSV65809996; called by muse, mutect2
- PISD | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100338712; called by muse, mutect2, varscan2
- PIWIL1 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.366); catalogued as COSV99807065; called by muse, mutect2, varscan2
- PKD1L1 | c.1315C>A p.H439N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV99221851; called by muse, mutect2, varscan2
- PKHD1 | c.5846A>G p.E1949G | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs751894216, COSV100583913, COSV61898707; called by muse, mutect2, varscan2
820 further variants in this file (454 protein-altering or splice-affecting, 327 silent, 39 other) are not listed here.
